Somatic mutation profile of tumor specimen TCGA-EY-A1GD-01A (aliquot TCGA-EY-A1GD-01A-11D-A13L-09) from TCGA case TCGA-EY-A1GD, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 51.0 years (18,638 days).
Specimen TCGA-EY-A1GD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5346608-8d03-46c2-9954-219177005d0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GD-10A (Blood Derived Normal), aliquot TCGA-EY-A1GD-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c2f459a-49d8-43be-8a90-35af14a78208

The open-access MAF lists 1,215 somatic variants for this specimen: 960 protein-altering or splice-affecting, 218 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 826, Silent 218, Nonsense Mutation 114, Intron 17, RNA 13, Splice Site 8, Frame Shift Ins 5, Splice Region 5, 5'UTR 3, 3'Flank 2, Translation Start Site 2, 3'UTR 1.

Variants (750 of 1,215; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as rs1326410920, COSV57358439; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 14/34 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- DEPDC5 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as rs886039255, CM164373, COSV99835332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DEPDC5 | c.1663C>T p.R555* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as rs587776973, CM134008, COSV56693269; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYRK1A | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs797045041, COSV58292419; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EDA | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs132630312, CM980583, COSV65772037; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 16/34 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NPHP3 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | catalogued as rs1485445500, COSV58629409; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 23/49 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RPS6KA3 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs122454129, CM991111, COSV65389911; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as COSV100588935; called by muse, mutect2, varscan2
- AADACL2 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV100735827; called by muse, mutect2, varscan2
- ABCA13 | c.12664G>A p.A4222T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as rs199630218, COSV101291424; called by muse, varscan2
- ABCA4 | c.3974C>T p.P1325L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs371582683; called by muse, mutect2, varscan2
- ABCA5 | c.4427G>A p.R1476Q | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs750426352, COSV67015792; called by muse, mutect2, varscan2
- ABCB4 | c.605T>G p.F202C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs781560404, COSV99711128; called by muse, mutect2, varscan2
- ABL2 | c.2103C>A p.F701L (on ENST00000502732 / NM_007314.4; = p.F686L on NM_005158.5) | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV61013261; called by muse, mutect2, varscan2
- ABLIM2 | c.1681C>T p.R561C (on ENST00000341937 / NM_001130084.2; = p.R471C on NM_032432.5) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs755982683, COSV56404836; called by muse, mutect2, varscan2
- ACVR2A | c.1037A>C p.K346T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.09); catalogued as COSV99604458; called by muse, mutect2, varscan2
- ADAM32 | c.1409A>G p.E470G | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.036); catalogued as COSV101165478; called by muse, mutect2, varscan2
- ADAMDEC1 | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.108); catalogued as COSV99836270; called by muse, mutect2, varscan2
- ADAMTS1 | c.2127G>T p.K709N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV53173236; called by muse, mutect2, varscan2
- ADAMTS19 | c.1338C>A p.F446L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV99180261; called by muse, mutect2, varscan2
- ADAMTS3 | c.2510A>G p.N837S | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV99711883; called by muse, mutect2, varscan2
- ADAMTS3 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV99711885; called by muse, mutect2, varscan2
- ADAMTS6 | c.1074-1G>T p.X358_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | catalogued as COSV101125320; called by muse, mutect2, varscan2
- ADAMTS7 | c.2357A>G p.K786R | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV101183223; called by muse, mutect2
- ADAMTSL3 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs757231468, COSV99720791; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1739T>C p.V580A | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV99647812; called by muse, mutect2, varscan2
- ADCY10 | c.1631C>A p.S544* | Nonsense Mutation (SNP) | VAF 57/125 reads (46%) | catalogued as COSV100897043, COSV63241188; called by muse, mutect2, varscan2
- ADCY2 | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57866723; called by muse, mutect2, varscan2
- ADGRF3 | c.388C>A p.L130M (on ENST00000311519 / NM_001145168.1; = p.L71M on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as COSV100275331; called by muse, mutect2, varscan2
- ADGRV1 | c.12424C>T p.R4142W | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs534226753, COSV67978187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AK9 | c.3076C>A p.L1026I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58143321; called by muse, mutect2, varscan2
- AKAP6 | c.4040A>T p.K1347M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99803812; called by muse, mutect2, varscan2
- AL713999.2 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV55279662, COSV99826072; called by muse, mutect2, varscan2
- ALDH1L1 | c.2476C>T p.R826W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375074619; called by muse, mutect2, varscan2
- ALG13 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 24/41 reads (59%) | catalogued as COSV52634896; called by muse, mutect2, varscan2
- ALG5 | c.810C>A p.F270L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV53505210; called by muse, mutect2, varscan2
- ALK | c.3686T>C p.V1229A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101202594; called by muse, mutect2, varscan2
- ALPK1 | c.1634T>G p.F545C | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.527); catalogued as COSV99455033; called by muse, mutect2, varscan2
- ALPK3 | c.4225G>A p.E1409K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV99359939; called by muse, mutect2, varscan2
- ALS2CL | c.2468A>C p.N823T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); catalogued as COSV100015281; called by muse, mutect2, varscan2
- AMER2 | c.1763C>A p.S588Y | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100766365; called by muse, mutect2, varscan2
- ANAPC1 | c.5323C>T p.L1775F | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1474589976, COSV100595035; called by muse, mutect2, varscan2
- ANK1 | c.4901T>G p.L1634R | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); catalogued as rs1402646676, COSV99226583; called by muse, mutect2, varscan2
- ANKK1 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1201722436, COSV100393024; called by muse, mutect2, varscan2
- ANKRD30A | c.3565G>T p.E1189* (on ENST00000611781; = p.E1133* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as rs1386752442, COSV100654309; called by muse, mutect2, varscan2
- ANKRD50 | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as COSV101538877, COSV72385130; called by muse, mutect2, varscan2
- ANKRD54 | c.822A>C p.K274N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as rs748498656, COSV99316557; called by muse, varscan2
- ANO4 | c.353G>A p.R118Q (on ENST00000392977 / NM_001286615.2; = p.R83Q on NM_178826.4) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); catalogued as rs755363477, COSV54605513, COSV54607261; called by muse, mutect2, varscan2
- ANPEP | c.875A>C p.K292T | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100263446; called by muse, mutect2, varscan2
- AOC3 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs766793528, COSV53828577; called by muse, mutect2, varscan2
- AP3M2 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99441532; called by muse, mutect2, varscan2
- AP4E1 | c.822A>C p.Q274H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs991693986, COSV99957100; called by muse, mutect2, varscan2
- APBA2 | c.910A>C p.T304P | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV101382505; called by muse, mutect2, varscan2
- APOL5 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs768415716, COSV50766598; called by muse, mutect2
- APTX | c.34A>G p.S12G | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100541433; called by muse, mutect2, varscan2
- ARAP2 | c.2362A>C p.N788H | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.361); catalogued as rs1449942577, COSV100395162; called by muse, mutect2, varscan2
- ARAP3 | c.4569G>T p.Q1523H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99499183; called by muse, mutect2, varscan2
- ARHGAP12 | c.1654G>T p.E552* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV60967024; called by muse, mutect2, varscan2
- ARHGAP21 | c.3989C>T p.T1330M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328876534, COSV100256589; called by muse, mutect2, varscan2
- ARHGAP22 | c.1944dup p.Y649Ifs*12 | Frame Shift Ins (INS) | VAF 25/71 reads (35%) | catalogued as rs1256821192; called by mutect2, pindel, varscan2
- ARHGAP28 | c.2140C>T p.R714C (on ENST00000383472 / NM_001366230.1; = p.R555C on NM_001010000.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV58655431; called by mutect2, varscan2
- ARHGAP30 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100920468; called by muse, mutect2, varscan2
- ARHGAP32 | c.2470T>C p.Y824H (on ENST00000310343 / NM_001378025.1; = p.Y475H on NM_014715.4) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.243); catalogued as rs775103279; called by muse, mutect2
- ARHGAP35 | c.2740G>T p.E914* | Nonsense Mutation (SNP) | VAF 20/44 reads (45%) | catalogued as COSV68330154; called by muse, mutect2, varscan2
- ARHGAP35 | c.4060T>G p.L1354V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV101351548; called by muse, mutect2, varscan2
- ARHGEF1 | c.2607A>C p.E869D | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV100529175; called by muse, mutect2, varscan2
- ARHGEF10 | c.923C>A p.S308Y (on ENST00000398564; = p.S283Y on NM_014629.4) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV100035443; called by muse, varscan2
- ARHGEF12 | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100755169; called by muse, mutect2
- ARID5B | c.1864T>G p.Y622D | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV99690312; called by muse, mutect2, varscan2
- ARL4A | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 32/78 reads (41%) | catalogued as COSV100775955; called by muse, mutect2, varscan2
- ARL6 | c.232A>C p.N78H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1335196581, COSV100256572; called by muse, mutect2, varscan2
- ASCC1 | c.434G>A p.R145Q (on ENST00000342444 / NM_001369085.1; = p.R117Q on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs779932786, COSV100403693; called by muse, mutect2, varscan2
- ASTN1 | c.868A>C p.S290R | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV99922816; called by muse, mutect2, varscan2
- ATF7IP | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs779331911, COSV53766269; called by muse, mutect2, varscan2
- ATM | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769166447, CM1314652, COSV53734045, COSV53758870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.4255C>A p.L1419I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53761365; called by muse, mutect2, varscan2
- ATP11C | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452216664, COSV59564239; called by muse, mutect2, varscan2
- ATP13A4 | c.3481G>A p.D1161N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as rs1394927551, COSV100710670; called by muse, mutect2, varscan2
- ATP1A4 | c.3038T>G p.L1013R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as COSV100927352; called by muse, mutect2, varscan2
- ATP1B1 | c.536A>C p.K179T | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100891634; called by muse, mutect2, varscan2
- ATP2B3 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as rs782615379, COSV54848065; called by muse, mutect2, varscan2
- ATP8B3 | c.1052T>C p.V351A | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV100034896; called by muse, mutect2, varscan2
- ATRX | c.2418G>T p.K806N | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64882427; called by muse, mutect2, varscan2
- ATRX | c.2049A>C p.E683D | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV100971318; called by muse, mutect2, varscan2
- ATXN2 | c.2290G>T p.E764* (on ENST00000550104; = p.E604* on NM_002973.4) | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV101112897; called by muse, mutect2
- ATXN3L | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as COSV66076212; called by muse, mutect2, varscan2
- AVEN | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100145752; called by muse, mutect2, varscan2
- B4GALT6 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99031004, COSV99380295; called by muse, mutect2, varscan2
- BCHE | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as rs780411054, COSV52254483; called by muse, mutect2, varscan2
- BHMT | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs372541519, COSV99165498; called by muse, mutect2, varscan2
- BIRC6 | c.1727A>C p.K576T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.138); catalogued as COSV101428693; called by muse, mutect2, varscan2
- BMP15 | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs782470052, COSV99399498; called by muse, mutect2, varscan2
- BPIFC | c.1278T>G p.N426K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99322395; called by muse, mutect2, varscan2
- BPIFC | c.88A>C p.I30L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.142); catalogued as COSV100301226; called by muse, mutect2, varscan2
- BPNT1 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100435808; called by muse, mutect2, varscan2
- BRCA2 | c.2862G>T p.E954D | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV66449619; called by muse, mutect2, varscan2
- BRD3 | c.71dup p.E25Gfs*51 | Frame Shift Ins (INS) | VAF 7/22 reads (32%) | catalogued as rs763134487; called by mutect2, varscan2
- BRD8 | c.447G>T p.K149N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1217534460, COSV99136562; called by muse, mutect2, varscan2
- BRDT | c.510A>C p.K170N | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100746570; called by muse, mutect2, varscan2
- BRIP1 | c.3434A>C p.E1145A | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV51999851, COSV99370856; called by muse, mutect2
- BRWD3 | c.2888C>T p.S963L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.069); catalogued as COSV64751280; called by muse, mutect2, varscan2
- BTBD8 | c.921C>A p.F307L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs758203077, COSV100730433, COSV61547145; called by muse, mutect2, varscan2
- BUD13 | c.328A>G p.N110D | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs145445291; called by muse, mutect2, varscan2
- BZW1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs1338043218, COSV100729882; called by muse, mutect2, varscan2
- C10orf71 | c.2021G>A p.R674K | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs200604581, COSV100110584, COSV60507083; called by muse, mutect2, varscan2
- C14orf119 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV52976605; called by muse, mutect2, varscan2
- C1QTNF2 | c.349G>A p.D117N (on ENST00000393975; = p.D72N on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as rs778660931, COSV67432609; called by muse, mutect2, varscan2
- C1orf116 | c.1327A>G p.I443V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as COSV100848007; called by muse, mutect2
- C3 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.272); catalogued as COSV99837139; called by muse, mutect2, varscan2
- C6 | c.2000A>G p.D667G | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs375991339; called by muse, mutect2, varscan2
- C7orf57 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs1028445620, COSV62362568; called by muse, mutect2, varscan2
- CA1 | c.177A>C p.E59D | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.359); catalogued as COSV56278068, COSV99810165; called by muse, mutect2, varscan2
- CA5B | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769895567, COSV59415801; called by muse, mutect2, varscan2
- CACNA1D | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs35057005; called by muse, mutect2, varscan2
- CACNA1E | c.3919G>A p.A1307T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs373085902; called by muse, mutect2, varscan2
- CACNA1H | c.3684C>A p.F1228L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.109); catalogued as rs369508525, COSV100673371; called by muse, mutect2, varscan2
- CACNA2D3 | c.1738A>G p.T580A | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99876548; called by muse, mutect2, varscan2
- CACNG4 | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100047847; called by muse, mutect2, varscan2
- CAD | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs750351929, COSV53032038; called by muse, mutect2, varscan2
- CAD | c.6190C>T p.R2064C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53023698, COSV53029560; called by muse, mutect2, varscan2
- CADPS2 | c.887T>G p.F296C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV57374234; called by muse, mutect2, varscan2
- CALHM4 | c.688G>T p.E230* (on ENST00000368596 / NM_001366078.1; = p.E44* on NM_153036.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100888900; called by muse, mutect2, varscan2
- CAPN9 | c.1622A>C p.E541A | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV99680993; called by muse, mutect2
- CARMIL3 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.811); catalogued as COSV100549808; called by muse, mutect2, varscan2
- CASK | c.2344G>A p.E782K (on ENST00000378163 / NM_001367721.1; = p.E777K on NM_003688.3) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746017736, COSV59367374; called by muse, mutect2, varscan2
- CASQ2 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121434549, CM013693, COSV54770079; called by muse, mutect2, varscan2
- CBFA2T3 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs147184929; called by muse, mutect2, varscan2
- CBL | c.1837G>T p.E613* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV50643348; called by muse, mutect2, varscan2
- CBLB | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV99914168; called by muse, mutect2, varscan2
- CBLIF | c.665A>G p.D222G | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99951071; called by muse, mutect2, varscan2
- CBLL1 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.162); catalogued as COSV99755333; called by muse, mutect2, varscan2
- CC2D2A | c.2524A>G p.T842A | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101052887; called by muse, mutect2, varscan2
- CCDC102B | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100104667; called by muse, mutect2, varscan2
- CCDC3 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as rs778117350, COSV66558364; called by muse, mutect2, varscan2
- CCDC39 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs199526690, COSV99868953; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC50 | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs761351849, COSV101165349; called by muse, varscan2
- CCDC74A | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs141323157; called by muse, mutect2, varscan2
- CCDC83 | c.809C>T p.T270I (on ENST00000342404 / NM_001286159.2; = p.T301I on NM_173556.5) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs1238785329, COSV99721924; called by muse, mutect2, varscan2
- CCDC88A | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as COSV55059867, COSV99711078; called by muse, mutect2, varscan2
- CCDC88C | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs1393580848, COSV101106091; called by muse, mutect2, varscan2
- CCDC89 | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100320911, COSV57033632; called by muse, mutect2, varscan2
- CCNYL1 | c.395C>T p.T132I (on ENST00000295414 / NM_001330218.2; = p.T62I on NM_152523.2) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99776060; called by muse, mutect2, varscan2
- CCNYL1 | c.586C>T p.R196C (on ENST00000295414 / NM_001330218.2; = p.R126C on NM_152523.2) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as rs1217839974, COSV54942097; called by muse, mutect2, varscan2
- CCR4 | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as COSV100447500; called by muse, mutect2, varscan2
- CCT8L2 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as COSV63461624, COSV63463703; called by muse, mutect2, varscan2
- CD19 | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.561); catalogued as COSV100218245; called by muse, mutect2
- CD79B | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV50075959, COSV50076941; called by muse, mutect2, varscan2
- CD84 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 47/104 reads (45%) | catalogued as COSV100246242; called by muse, mutect2, varscan2
- CD99 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV101153290; called by muse, mutect2
- CDC20B | c.1372A>G p.K458E | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV99697309; called by muse, mutect2, varscan2
- CDH11 | c.1789G>A p.V597M | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV51758504; called by muse, mutect2, varscan2
- CDH12 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 73/149 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV101203271; called by muse, mutect2, varscan2
- CDH24 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV99400221; called by muse, mutect2, varscan2
- CDH8 | c.1972G>T p.E658* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100183823; called by muse, mutect2, varscan2
- CDK10 | c.778G>T p.E260* (on ENST00000353379 / NM_052988.5; = p.E189* on NM_052987.4) | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99232483; called by muse, mutect2, varscan2
- CDYL | c.433T>G p.F145V (on ENST00000328908 / NM_001368125.1; = p.F91V on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs1300031654, COSV100189970; called by muse, mutect2, varscan2
- CEACAM19 | c.137A>G p.N46S | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV100715504; called by muse, mutect2, varscan2
- CEACAM3 | c.347A>G p.D116G | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs781892237, COSV55762896, COSV99705095; called by muse, mutect2
- CELSR2 | c.6107T>G p.F2036C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); catalogued as COSV99604605; called by muse, mutect2, varscan2
- CENPF | c.439A>C p.K147Q | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV65280429; called by muse, mutect2, varscan2
- CEP162 | c.3853G>T p.E1285* | Nonsense Mutation (SNP) | VAF 25/47 reads (53%) | catalogued as COSV100003294; called by muse, mutect2, varscan2
- CEP170 | c.4625G>A p.R1542K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.374); catalogued as rs757113593, COSV100317706; called by muse, mutect2, varscan2
- CEP350 | c.4873C>T p.R1625* | Nonsense Mutation (SNP) | VAF 5/59 reads (8%) | catalogued as rs1181129362, COSV62601953; called by muse, mutect2
- CFAP65 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147627348; called by muse, mutect2, varscan2
- CFAP65 | c.68T>C p.F23S | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99838429; called by muse, mutect2, varscan2
- CFAP69 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV100290396; called by muse, mutect2, varscan2
- CFAP94 | c.1619T>G p.I540S (on ENST00000320267 / NM_001352064.2; = p.I546S on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV100209674; called by muse, mutect2, varscan2
- CFAP97 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs373566490, COSV57109285; called by muse, mutect2, varscan2
- CFHR1 | c.371A>G p.E124G | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.702); catalogued as COSV100258960; called by muse, mutect2, varscan2
- CFHR5 | c.4T>G p.L2V | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.227); catalogued as COSV99889538; called by muse, mutect2, varscan2
- CGRRF1 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV99370546; called by muse, varscan2
- CHD2 | c.4910G>A p.R1637Q | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as rs752891322, COSV101245878; called by muse, mutect2, varscan2
- CHML | c.1016T>G p.V339G | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100087731; called by muse, mutect2, varscan2
- CHRNB1 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as rs1222717958, COSV53439082; called by muse, mutect2, varscan2
- CHRNB2 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1429118769, COSV100872665; called by muse, mutect2, varscan2
- CIBAR1 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as rs764514673, COSV63897064; called by muse, mutect2, varscan2
- CINP | c.76A>G p.N26D | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as rs562361918, COSV99392231; called by muse, mutect2, varscan2
- CLDN3 | c.134T>C p.I45T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV101230851; called by muse, mutect2, varscan2
- CLMN | c.1717T>G p.F573V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV100112826; called by muse, mutect2, varscan2
- CLOCK | c.2261C>T p.T754M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.451); catalogued as rs538817792, COSV100011621; called by muse, mutect2, varscan2
- CLTC | c.3044A>C p.N1015T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.052); catalogued as COSV99292799; called by muse, mutect2, varscan2
- CMPK1 | c.226A>C p.N76H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as COSV100898592; called by muse, mutect2, varscan2
- CMYA5 | c.3061C>T p.L1021F | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV101484302, COSV71405749; called by muse, mutect2
- CMYA5 | c.3778C>A p.L1260I | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs1193096769, COSV71404537; called by muse, mutect2, varscan2
- CMYA5 | c.7696G>A p.E2566K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs200615970; called by muse, varscan2
- CNFN | c.321A>C p.E107D | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99706222; called by muse, mutect2, varscan2
- CNOT7 | c.34A>C p.I12L | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100246656; called by muse, mutect2, varscan2
- COA1 | c.426A>C p.E142D | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99786687; called by muse, mutect2, varscan2
- COL11A1 | c.4543A>G p.K1515E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100617894; called by muse, mutect2, varscan2
- COL11A1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.114); catalogued as rs372387693; called by muse, mutect2, varscan2
- COL1A2 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.049); catalogued as COSV99800817; called by muse, mutect2, varscan2
- COL5A1 | c.3752C>T p.P1251L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs755735075, CD001481, COSV100879981, COSV100880483; called by muse, mutect2
- COL6A1 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs367650141; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL9A1 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.937); catalogued as rs761249181, COSV100295424; called by muse, varscan2
- CPAMD8 | c.1777C>T p.H593Y (on ENST00000651564; = p.H546Y on NM_015692.5) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.212); catalogued as COSV52237862; called by mutect2, varscan2
- CPO | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99786622; called by muse, mutect2, varscan2
- CPSF7 | c.489G>T p.Q163H (on ENST00000394888 / NM_001136040.4; = p.Q206H on NM_024811.4) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.451); catalogued as COSV100467562; called by muse, mutect2, varscan2
- CR1 | c.4465C>T p.R1489* | Nonsense Mutation (SNP) | VAF 76/302 reads (25%) | catalogued as rs778591697, COSV65456307; called by muse, mutect2, varscan2
- CREG1 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV100981918; called by muse, mutect2, varscan2
- CROT | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100519656, COSV58977291; called by muse, mutect2, varscan2
- CRX | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.136); catalogued as COSV99704630; called by muse, mutect2, varscan2
- CSHL1 | c.647T>C p.V216A (on ENST00000309894 / NM_022581.3; = p.V122A on NM_001318.4) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.746); catalogued as COSV99368160; called by muse, mutect2
- CSMD1 | c.4912T>G p.L1638V (on ENST00000520002; = p.L1637V on NM_033225.6) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100152903, COSV59382787; called by muse, mutect2, varscan2
- CSMD2 | c.338C>A p.S113Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs1403199948, COSV53887331, COSV99588413; called by muse, mutect2, varscan2
- CSTF2 | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV65895464; called by muse, mutect2, varscan2
- CTBP2 | c.1083C>A p.F361L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV100456847; called by muse, mutect2, varscan2
- CTCFL | c.1433A>C p.K478T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99713209; called by muse, mutect2, varscan2
- CTNNA1 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV57069821; called by muse, mutect2, varscan2
- CXCR3 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV101031719; called by muse, mutect2, varscan2
- CYP2U1 | c.536A>C p.K179T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100256804; called by muse, mutect2, varscan2
- CYP3A7 | c.676T>G p.F226V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV100312843; called by muse, mutect2
- CYP4F2 | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1468770714, COSV99686263; called by muse, mutect2, varscan2
- CYP4F22 | c.269A>C p.D90A | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV99513082; called by muse, mutect2, varscan2
- DACH1 | c.1591+1G>A p.X531_splice (on ENST00000619232 / NM_001366712.1; = p.X479_splice on NM_080759.6) | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as COSV57501819; called by muse, mutect2, varscan2
- DBX1 | c.599T>A p.F200Y | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99910302; called by muse, mutect2, varscan2
- DCAF4L1 | c.1080G>T p.E360D | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100295928, COSV60788575; called by muse, mutect2
- DDHD2 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.652); catalogued as rs143549962, COSV68157742; called by muse, mutect2, varscan2
- DDX53 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100029071, COSV60068844; called by muse, mutect2, varscan2
- DGKE | c.1498C>T p.R500* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as rs1342368899, COSV52349569; called by muse, mutect2, varscan2
- DIAPH2 | c.1939G>T p.E647* | Nonsense Mutation (SNP) | VAF 39/90 reads (43%) | catalogued as COSV100234777; called by muse, mutect2, varscan2
- DICER1 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58615252, COSV58618257; called by muse, mutect2, varscan2
- DLG4 | c.586G>A p.E196K (on ENST00000399506 / NM_001321075.3; = p.E239K on NM_001365.4) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV57240615; called by muse, mutect2, varscan2
- DLL1 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs149451070; called by muse, mutect2, varscan2
- DMBT1 | c.5597T>C p.V1866A (on ENST00000338354 / NM_001377530.1; = p.V1109A on NM_004406.3) | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV100353959; called by muse, mutect2, varscan2
- DMD | c.3770A>C p.K1257T | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100822236; called by muse, mutect2, varscan2
- DNAH1 | c.8171G>A p.R2724Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1224891381, COSV101326875; called by muse, mutect2, varscan2
- DNAH10 | c.7120G>T p.D2374Y (on ENST00000409039; = p.D2313Y on NM_207437.3) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV101292556; called by muse, mutect2, varscan2
- DNAH11 | c.2618A>C p.K873T | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV100180480; called by muse, mutect2, varscan2
- DNAH2 | c.5524T>C p.Y1842H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1291951429, COSV101209554; called by muse, mutect2, varscan2
- DNAH7 | c.5315C>T p.A1772V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs748432820, COSV100415893; called by muse, mutect2, varscan2
- DNAH8 | c.13050C>A p.F4350L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1404091935, COSV59443699; called by muse, mutect2
- DNAH9 | c.7318G>A p.E2440K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs764734290, COSV52356485; called by muse, mutect2, varscan2
- DNAI3 | c.786C>A p.F262L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV99642312; called by muse, mutect2, varscan2
- DNAJC10 | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.347); catalogued as COSV99899558; called by muse, mutect2
- DNAJC5G | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as rs1232215286, COSV56081339; called by muse, mutect2, varscan2
- DNHD1 | c.11657A>C p.K3886T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99600848; called by muse, mutect2, varscan2
- DOCK10 | c.4333C>T p.R1445* | Nonsense Mutation (SNP) | VAF 29/80 reads (36%) | catalogued as rs764765523, COSV51418209; called by muse, mutect2, varscan2
- DOCK3 | c.2953C>T p.R985W | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs745697151, COSV99814571; called by muse, mutect2, varscan2
- DOCK5 | c.818A>C p.K273T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.468); catalogued as COSV99377664; called by muse, mutect2, varscan2
- DOCK7 | c.803A>C p.K268T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99225716; called by muse, mutect2, varscan2
- DPYD | c.1489A>C p.K497Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100929323; called by muse, mutect2, varscan2
- DRD1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs1431381197, COSV101192522, COSV67104817; called by muse, mutect2, varscan2
- DRP2 | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs766073418, COSV101235182; called by muse, mutect2, varscan2
- DSC3 | c.278C>A p.S93* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as COSV64572431; called by muse, mutect2, varscan2
- DSCAM | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as rs750290290, COSV68027085; called by muse, mutect2, varscan2
- DSCAM | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761826018, COSV101261377; called by muse, mutect2, varscan2
- DSCAML1 | c.2675A>G p.D892G (on ENST00000321322; = p.D832G on NM_020693.4) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV100356956; called by muse, mutect2, varscan2
- DSG1 | c.820-2A>G p.X274_splice | Splice Site (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99936456; called by muse, varscan2
- DST | c.15562G>C p.A5188P (on ENST00000361203 / NM_001374722.1; = p.A2776P on NM_015548.5) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55025497, COSV99759291; called by muse, mutect2, varscan2
- DST | c.15088G>T p.E5030* (on ENST00000361203 / NM_001374722.1; = p.E2618* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 19/36 reads (53%) | catalogued as COSV55011440, COSV99759083; called by muse, mutect2, varscan2
- DTNA | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV99314796; called by muse, mutect2, varscan2
- DTYMK | c.336T>G p.F112L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.95); PolyPhen benign (0.107); catalogued as COSV99994895; called by muse, mutect2, varscan2
- DUSP4 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99529948; called by muse, mutect2, varscan2
- DYRK3 | c.1144T>G p.L382V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100895808; called by muse, mutect2, varscan2
- ECE1 | c.813A>C p.K271N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV99942248; called by muse, mutect2, varscan2
- ECT2L | c.1536A>C p.Q512H | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV100872163; called by muse, mutect2, varscan2
- EEA1 | c.2526A>C p.Q842H | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs1565814042, COSV100468361; called by muse, mutect2, varscan2
- EED | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 28/47 reads (60%) | catalogued as COSV54553414; called by muse, mutect2, varscan2
- EFCAB1 | c.94T>G p.F32V | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV100030969; called by muse, mutect2, varscan2
- EFCAB5 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as rs752078600, COSV57931324; called by muse, mutect2, varscan2
- EFCAB7 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as rs781221854, COSV64314100; called by muse, mutect2, varscan2
- EFR3A | c.361A>G p.N121D | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV99603511; called by muse, mutect2, varscan2
- EHMT1 | c.3347G>A p.R1116Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs769124795, COSV101509724; called by muse, mutect2, varscan2
- EHMT1 | c.3769C>T p.R1257C | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV101135084; called by muse, mutect2, varscan2
- EI24 | c.727T>G p.F243V | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.059); catalogued as COSV99629211; called by muse, mutect2, varscan2
- EIF2AK3 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs766640012, COSV57545364; called by muse, mutect2, varscan2
- EIF2S2 | c.570G>T p.K190N | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); catalogued as COSV66620870; called by muse, mutect2
- EIF2S3 | c.1119T>G p.I373M | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.694); catalogued as COSV99451109; called by muse, mutect2, varscan2
- EIF3B | c.1996G>A p.V666I | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.342); catalogued as rs370274071, COSV100703659; called by muse, mutect2, varscan2
- EIF4A2 | c.890A>C p.D297A | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV99961342; called by muse, mutect2
- EIF4G3 | c.2275C>T p.R759* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as COSV51677587; called by muse, mutect2
- ELFN2 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs759330097, COSV68745751; called by muse, mutect2, varscan2
- ELP3 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751119272, COSV56461939; called by muse, mutect2, varscan2
- ENOX2 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.04); catalogued as COSV100584508; called by muse, mutect2, varscan2
- ENPP2 | c.979A>C p.N327H (on ENST00000075322 / NM_001040092.3; = p.N379H on NM_006209.5) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV99309212; called by muse, mutect2, varscan2
- EP400 | c.6607G>A p.D2203N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.552); catalogued as rs1391780202, COSV57762284; called by muse, mutect2, varscan2
- EPB41L1 | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as COSV99151502; called by muse, mutect2, varscan2
- EPC2 | c.1849A>C p.K617Q | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV99310100; called by muse, mutect2, varscan2
- ERCC6 | c.1949A>C p.K650T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100876138; called by muse, mutect2, varscan2
- ERICH6 | c.1227T>G p.I409M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.263); catalogued as COSV99901926; called by muse, mutect2, varscan2
- ERVFRD-1 | c.271A>C p.S91R | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.244); catalogued as COSV100977426; called by muse, mutect2, varscan2
- ERVW-1 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.32); PolyPhen benign (0.051); catalogued as rs777447724, COSV71259377; called by muse, mutect2, varscan2
- ESCO2 | c.850A>C p.K284Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV100533381; called by muse, mutect2, varscan2
- ESRRB | c.307T>C p.C103R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99835675; called by muse, mutect2, varscan2
- ESS2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs370053001; called by muse, mutect2, varscan2
- EVX2 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as COSV100420821, COSV57963393; called by muse, mutect2, varscan2
- EXPH5 | c.3581A>C p.K1194T | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV99762077; called by muse, mutect2
- F5 | c.4930C>A p.L1644I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63128465; called by muse, mutect2, varscan2
- F8 | c.6734C>T p.P2245L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV100371808; called by muse, mutect2, varscan2
- F8 | c.5473T>G p.F1825V | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.074); catalogued as COSV100811827; called by muse, mutect2, varscan2
- F8 | c.641T>G p.F214C | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM122066, CM123889, COSV100811828; called by muse, mutect2, varscan2
- FABP12 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as COSV64616811, COSV64616879; called by muse, mutect2, varscan2
- FAM107B | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV51684874, COSV51686308; called by muse, mutect2, varscan2
- FAM135B | c.3477G>T p.K1159N | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99426486, COSV99426834; called by muse, mutect2, varscan2
- FAM153A | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 38/113 reads (34%) | catalogued as rs1231236575, COSV100647113; called by muse, mutect2, varscan2
- FAM71D | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as COSV100315364; called by muse, mutect2, varscan2
- FAM83B | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100174914; called by muse, mutect2, varscan2
- FAM83C | c.549G>T p.M183I | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV100981677; called by muse, mutect2, varscan2
- FANCD2 | c.1060A>G p.I354V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99812257; called by muse, mutect2, varscan2
- FANCD2 | c.1188G>T p.K396N | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55035136; called by muse, varscan2
- FASTKD2 | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52697342; called by muse, mutect2, varscan2
- FAT1 | c.13294G>A p.E4432K | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1276553545, COSV71676245; called by muse, mutect2, varscan2
- FAT1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV71672770; called by muse, mutect2, varscan2
- FAT2 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as rs371264512; called by muse, mutect2, varscan2
- FAT3 | c.12079C>T p.R4027C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs1448732021, COSV99970155; called by muse, mutect2, varscan2
- FBN1 | c.2996G>A p.R999K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100356212; called by muse, mutect2, varscan2
- FBXL3 | c.805T>G p.F269V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV100842392; called by muse, mutect2, varscan2
- FBXO9 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs753933679, COSV55055392; called by muse, mutect2, varscan2
- FCGR2A | c.716T>C p.I239T (on ENST00000271450 / NM_001136219.3; = p.I238T on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/494 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.549); catalogued as COSV99615674; called by muse, mutect2, varscan2
- FCRL2 | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100829990; called by muse, mutect2, varscan2
- FER1L6 | c.3150A>G p.E1050= | Splice Region (SNP) | VAF 23/49 reads (47%) | catalogued as COSV101206142; called by muse, mutect2
- FEZF1 | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV100484544; called by muse, mutect2, varscan2
- FGB | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.136); catalogued as COSV100122542; called by muse, mutect2, varscan2
- FGD2 | c.472T>G p.Y158D | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV99236564; called by muse, mutect2, varscan2
- FIG4 | c.1168C>A p.L390M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100020170; called by muse, mutect2, varscan2
- FMO1 | c.580A>C p.N194H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100707902; called by muse, mutect2
- FN1 | c.1543C>T p.R515* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as rs371349369, COSV100118052; called by muse, mutect2, varscan2
- FRAS1 | c.3371C>T p.S1124F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV53591666; called by muse, mutect2, varscan2
- FRMPD2 | c.3728G>T p.R1243I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV100564118; called by mutect2, varscan2
- FRMPD3 | c.3754T>G p.L1252V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99346932; called by muse, mutect2, varscan2
- FRMPD4 | c.3331A>G p.T1111A | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101043861; called by muse, mutect2, varscan2
- FRYL | c.1663G>T p.D555Y | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51958434, COSV99977903; called by muse, mutect2, varscan2
- FSD2 | c.948G>T p.E316D | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0.023); catalogued as COSV100575266; called by muse, varscan2
- FSD2 | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 45/104 reads (43%) | catalogued as COSV100575268; called by muse, varscan2
- FSIP2 | c.17176G>A p.A5726T | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV100556142; called by muse, mutect2, varscan2
- FST | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV99887410; called by mutect2, varscan2
- FUZ | c.466A>G p.I156V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100571241; called by muse, mutect2, varscan2
- GABBR1 | c.2417G>A p.G806D | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100589995; called by muse, mutect2, varscan2
- GABBR1 | c.324A>C p.E108D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV100589997; called by muse, mutect2, varscan2
- GAD2 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as rs761233439, COSV99392433, COSV99393207; called by mutect2, varscan2
- GAS2L3 | c.181T>G p.L61V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV99903068; called by muse, mutect2, varscan2
- GCNA | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.097); catalogued as rs1398059703, COSV65467821; called by muse, mutect2, varscan2
- GCOM1 | c.152G>T p.R51I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51087967; called by muse, mutect2, varscan2
- GIMAP7 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as rs145339506, COSV57959733; called by muse, mutect2, varscan2
- GK5 | c.872T>C p.V291A | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV101242318; called by muse, mutect2, varscan2
- GLIPR2 | c.196A>G p.N66D | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV100936979; called by muse, mutect2, varscan2
- GNE | c.1248G>T p.K416N (on ENST00000396594 / NM_001128227.3; = p.K385N on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100930112; called by muse, mutect2, varscan2
- GOLGB1 | c.6137A>G p.E2046G | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs762014005, COSV100511431; called by muse, mutect2, varscan2
- GOT1L1 | c.26A>G p.D9G | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100294664; called by muse, mutect2, varscan2
- GPAM | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100788392; called by muse, mutect2, varscan2
- GPC3 | c.970T>C p.F324L | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.597); catalogued as COSV100893497; called by muse, mutect2
- GPR171 | c.937T>G p.L313V | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV99854404; called by muse, mutect2, varscan2
- GPR26 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs141519939, COSV99500787; called by muse, mutect2, varscan2
- GRAMD1B | c.1811C>T p.T604M | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV100455144; called by muse, mutect2, varscan2
- GRK3 | c.209A>C p.D70A | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV100151945; called by muse, mutect2, varscan2
- GRK5 | c.1388C>A p.P463H | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100963218; called by muse, mutect2, varscan2
- GSPT2 | c.622T>G p.F208V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100468325; called by muse, mutect2, varscan2
- GSTA5 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV99489706; called by muse, mutect2
- GUCY2C | c.2034A>C p.E678D | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.525); catalogued as COSV99664075; called by muse, mutect2
- H1-5 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100138053, COSV100138177; called by muse, mutect2, varscan2
- H2BC21 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100480136; called by muse, mutect2, varscan2
- H3-3A | c.111G>T p.K37N | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV64731928; called by muse, mutect2, varscan2
- HASPIN | c.1541C>A p.A514D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV99561465; called by muse, mutect2, varscan2
- HAUS5 | c.192C>A p.L64= | Splice Region (SNP) | VAF 24/41 reads (59%) | catalogued as COSV99178808; called by muse, mutect2, varscan2
- HBB | c.126C>A p.F42L | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as CD920864, COSV58941665; called by muse, mutect2, varscan2
- HCFC1 | c.5969G>T p.G1990V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100129757; called by muse, mutect2, varscan2
- HCRTR1 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs772807472, COSV101036291; called by muse, mutect2, varscan2
- HDLBP | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60493251; called by muse, mutect2, varscan2
- HEATR5A | c.6133T>C p.F2045L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101120458; called by muse, mutect2, varscan2
- HEATR5B | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs369680339, COSV51850221; called by muse, mutect2, varscan2
- HECA | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100866251; called by muse, mutect2, varscan2
- HECTD4 | c.4831C>T p.R1611W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566084907, COSV66386895; called by muse, mutect2, varscan2
- HEPH | c.3220G>A p.V1074I (on ENST00000343002; = p.V807I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1480245844, COSV57962196; called by muse, mutect2, varscan2
- HEPHL1 | c.1576G>A p.V526I | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); catalogued as rs748694729, COSV100244284; called by muse, mutect2, varscan2
- HHATL | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs144753590; called by muse, mutect2, varscan2
- HIC1 | c.1664G>A p.R555H (on ENST00000322941 / NM_001098202.1; = p.R536H on NM_006497.4) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99558633; called by muse, mutect2, varscan2
- HKDC1 | c.2168G>A p.R723Q | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs777790533, COSV100664737; called by muse, mutect2, varscan2
- HMCN1 | c.8286T>G p.I2762M | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99634553; called by muse, mutect2, varscan2
- HMCN1 | c.15284G>A p.G5095E | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54936602; called by muse, mutect2, varscan2
- HOXA5 | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99762470; called by muse, mutect2, varscan2
- HRNR | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 69/135 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs201065916, COSV100914064, COSV64258916; called by muse, mutect2, varscan2
- HUWE1 | c.5125G>T p.E1709* | Nonsense Mutation (SNP) | VAF 30/52 reads (58%) | catalogued as COSV53339016; called by muse, mutect2, varscan2
- HUWE1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV53339913; called by muse, mutect2, varscan2
- ICOS | c.25T>G p.F9V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.033); catalogued as COSV100320419; called by muse, mutect2, varscan2
- IDH3B | c.443T>G p.L148R | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100250300; called by muse, mutect2, varscan2
- IFI44L | c.203A>C p.N68T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.092); catalogued as COSV100655085; called by muse, mutect2, varscan2
- IFT172 | c.1994A>G p.E665G | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as COSV99563148; called by muse, mutect2, varscan2
- IFT57 | c.531C>A p.S177R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.171); catalogued as COSV52708325, COSV99198068; called by muse, mutect2, varscan2
- IGF2BP1 | c.99C>A p.F33L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.155); catalogued as COSV51733929, COSV99288975; called by muse, mutect2, varscan2
- IGF2R | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100806628; called by muse, mutect2, varscan2
- IL1RAPL2 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as COSV100781913, COSV61160693, COSV61187040; called by muse, mutect2, varscan2
- ILF3 | c.438A>G p.I146M | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99140144; called by muse, mutect2, varscan2
- INCA1 | c.535C>A p.R179S (on ENST00000574617 / NM_001167986.1; = p.R164S on NM_213726.2) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs761264162, COSV100742063, COSV61788118; called by muse, mutect2, varscan2
- INPP4B | c.430T>G p.F144V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.337); catalogued as COSV99526371; called by muse, mutect2, varscan2
- INSC | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV101089591; called by muse, varscan2
- INSC | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); catalogued as rs190828164, COSV65410313; called by muse, varscan2
- INTS3 | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.537); catalogued as rs1432776930, COSV100016424, COSV59675713; called by muse, mutect2, varscan2
- INTS6L | c.1056G>A p.W352* | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100878257; called by muse, mutect2, varscan2
- INTS6L | c.1529G>T p.R510I | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100878259; called by muse, mutect2, varscan2
- INTS6L | c.2260G>T p.D754Y | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100878260, COSV66085283; called by muse, mutect2, varscan2
- IQGAP2 | c.2711T>G p.F904C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99167912; called by muse, mutect2, varscan2
- IRAK3 | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.735); catalogued as COSV54161105, COSV99706129; called by muse, mutect2, varscan2
- ITGA6 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99905962; called by muse, mutect2, varscan2
- ITGA8 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.998); catalogued as COSV100959625; called by muse, mutect2, varscan2
- ITGA9 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99293792; called by muse, mutect2, varscan2
- ITGAM | c.53A>C p.N18T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99793019; called by muse, mutect2, varscan2
- ITLN2 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs753954745, COSV100600751; called by muse, mutect2, varscan2
- ITPKB | c.830A>C p.K277T | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV99685050; called by muse, mutect2, varscan2
- ITPR1 | c.1307C>A p.S436Y (on ENST00000354582; = p.S421Y on NM_002222.7) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100232883; called by muse, mutect2, varscan2
- ITPR2 | c.6188G>T p.R2063I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV67266662; called by muse, mutect2, varscan2
- ITSN2 | c.2697A>C p.E899D | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.525); catalogued as COSV100744083; called by muse, mutect2, varscan2
- JADE3 | c.647A>G p.D216G | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99510202; called by muse, mutect2, varscan2
- JPH4 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100436990; called by muse, mutect2, varscan2
- KAT7 | c.1310A>G p.D437G | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99372038; called by muse, mutect2, varscan2
- KBTBD2 | c.393G>T p.E131D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as COSV58363923; called by muse, mutect2, varscan2
- KBTBD7 | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as COSV101068190; called by muse, mutect2, varscan2
- KCNJ1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.031); catalogued as rs780690034, COSV60662313; called by muse, mutect2, varscan2
- KCNJ2 | c.884T>C p.V295A | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201162707, COSV99696504; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNMA1 | c.3722A>C p.K1241T (on ENST00000404771; = p.E1177D on NM_001014797.3) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.981); catalogued as COSV100972350; called by muse, mutect2
- KCNMA1 | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.142); catalogued as COSV99699317; called by muse, mutect2, varscan2
- KDM4C | c.2356C>T p.R786* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as rs374516052; called by muse, mutect2, varscan2
- KIAA0319 | c.188A>C p.D63A | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100985763, COSV65497289; called by muse, mutect2
- KIAA1210 | c.1245A>C p.Q415H | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101274362; called by muse, mutect2, varscan2
- KIAA1549 | c.2203G>A p.V735I | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV99651779; called by muse, mutect2, varscan2
- KIF16B | c.820A>G p.N274D | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs200023927, COSV100734824; called by muse, mutect2, varscan2
- KIF1A | c.2235G>T p.K745N | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100242148; called by muse, mutect2, varscan2
- KIF20B | c.1740A>G p.I580M | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs748313937, COSV99590616; called by muse, mutect2, varscan2
- KIF26A | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100181503; called by muse, mutect2, varscan2
- KIF26B | c.3706A>G p.S1236G | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs1222277749, COSV100833259; called by muse, mutect2, varscan2
- KIR2DL3 | c.194A>C p.K65T | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100668041; called by muse, mutect2, varscan2
- KLC4 | c.1809+2T>C p.X603_splice | Splice Site (SNP) | VAF 37/73 reads (51%) | catalogued as COSV99432508; called by muse, mutect2, varscan2
- KLHL20 | c.413T>C p.V138A | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99268623; called by muse, mutect2, varscan2
- KLHL23 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.322); catalogued as rs140221414, COSV55865633; called by muse, mutect2, varscan2
- KMT2C | c.7912T>C p.S2638P | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100075835, COSV51521210; called by muse, mutect2, varscan2
- KRT73 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs1210935768, COSV59837684, COSV99988492; called by muse, mutect2, varscan2
- KRT78 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs373055664, COSV100467573; called by muse, mutect2, varscan2
- KRTAP19-6 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 39/95 reads (41%) | catalogued as COSV100473989, COSV61843836; called by muse, mutect2, varscan2
- KRTAP27-1 | c.313T>G p.S105A | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as COSV101239764; called by muse, mutect2, varscan2
- L3MBTL1 | c.727C>T p.R243C (on ENST00000418998 / NM_001377303.1; = p.R153C on NM_015478.7) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1326323686, COSV100917306; called by muse, mutect2, varscan2
- LAMA2 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.16); catalogued as COSV101370775; called by muse, mutect2, varscan2
- LAMB3 | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); catalogued as COSV61917603; called by muse, mutect2, varscan2
- LCA5L | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.94); PolyPhen benign (0.013); catalogued as COSV99903856; called by muse, mutect2, varscan2
- LCE1F | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.026); catalogued as rs553837591, COSV57668776; called by muse, mutect2, varscan2
- LCE3B | c.72G>T p.K24N | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV59500977; called by muse, mutect2, varscan2
- LGALSL | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as rs757537218, COSV99482536; called by muse, mutect2, varscan2
- LIG3 | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV99253044; called by muse, mutect2, varscan2
- LIN54 | c.1930T>G p.L644V | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as COSV100464944; called by muse, mutect2, varscan2
- LINS1 | c.1307A>G p.K436R | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs751759286, COSV100130487; called by muse, mutect2
- LINS1 | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59078564; called by muse, mutect2, varscan2
- LINS1 | c.12C>A p.F4L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV100130490; called by muse, mutect2
- LMNA | c.1979A>G p.N660S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100738820; called by muse, mutect2, varscan2
- LMTK2 | c.3646G>A p.E1216K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as rs200864795, COSV99807568; called by muse, varscan2
- LMX1A | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 87/160 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760762235, COSV54221701; called by muse, mutect2, varscan2
- LPA | c.5641G>T p.E1881* | Nonsense Mutation (SNP) | VAF 36/83 reads (43%) | catalogued as COSV100307898, COSV100308042; called by muse, mutect2, varscan2
- LRCH2 | c.1802G>T p.R601I | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.206); catalogued as rs1556526810, COSV100407409, COSV100407452; called by muse, mutect2, varscan2
- LRFN2 | c.715T>G p.F239V | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as rs781621719, COSV100599876; called by muse, mutect2, varscan2
- LRFN5 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99985187; called by muse, mutect2, varscan2
- LRFN5 | c.1950G>T p.K650N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV99985189; called by muse, mutect2, varscan2
- LRIF1 | c.1942A>C p.N648H | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.351); catalogued as rs758847416, COSV100870907; called by muse, mutect2, varscan2
- LRIF1 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1293546269, COSV100870909; called by muse, mutect2, varscan2
- LRRC25 | c.691G>T p.V231L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV100170597; called by muse, mutect2, varscan2
- LRRC36 | c.1065G>T p.K355N | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.082); catalogued as COSV99339048; called by muse, mutect2, varscan2
- LRRC71 | c.1216G>T p.D406Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100504110; called by muse, mutect2, varscan2
- LRRK2 | c.6966G>T p.K2322N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs1262819853, COSV100111005, COSV54150145; called by muse, mutect2, varscan2
- LUC7L3 | c.710G>T p.R237I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.5); catalogued as COSV99537144; called by muse, varscan2
- LY6K | c.233T>G p.F78C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99456553; called by muse, mutect2, varscan2
- LY96 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as rs761017903, COSV99514672; called by muse, mutect2, varscan2
- LY96 | c.325A>C p.K109Q | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99514674; called by muse, mutect2, varscan2
- LYNX1 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs753398738, COSV100235767; called by muse, mutect2, varscan2
- LYST | c.1137G>T p.K379N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV101090135; called by muse, mutect2, varscan2
- LYVE1 | c.601T>C p.C201R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99811160; called by muse, mutect2, varscan2
- MAGEA8 | c.366C>A p.F122L | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.248); catalogued as COSV99674764; called by muse, mutect2, varscan2
- MAGEB4 | c.80T>G p.V27G | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100854792; called by muse, mutect2, varscan2
- MAGEC1 | c.1184G>T p.R395I | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99596377; called by muse, mutect2, varscan2
- MAGEC3 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs146435883, COSV53578665; called by muse, mutect2, varscan2
- MAGT1 | c.926T>G p.L309R (on ENST00000618282 / NM_001367916.1; = p.L341R on NM_032121.5) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100800410; called by muse, mutect2, varscan2
- MAP2 | c.796T>C p.F266L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.15); catalogued as COSV99561481; called by muse, mutect2, varscan2
- MAP2K2 | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1166526430, COSV99502669; called by muse, varscan2
- MAP2K4 | c.395G>T p.R132I | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100796478; called by muse, mutect2, varscan2
- MAT2A | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs754455888, COSV99290156; called by muse, mutect2, varscan2
- MB21D2 | c.173A>G p.E58G | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as COSV101165167; called by muse, mutect2, varscan2
- MBLAC2 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs776427772, COSV100353227; called by muse, mutect2, varscan2
- MBTD1 | c.1319T>G p.I440S | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100899319; called by muse, mutect2, varscan2
- MCF2L | c.2065T>G p.Y689D (on ENST00000375608; = p.Y657D on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99996120; called by muse, mutect2, varscan2
- MCHR2 | c.978G>T p.E326D | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV56001019, COSV99912565; called by muse, mutect2, varscan2
- MCM2 | c.1301T>A p.V434D | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99413416; called by muse, mutect2, varscan2
- MCTS1 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 54/139 reads (39%) | catalogued as COSV100989165; called by muse, mutect2, varscan2
- MDN1 | c.16165A>G p.I5389V | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs761884939, COSV101021749; called by muse, mutect2, varscan2
- MDN1 | c.7239G>T p.E2413D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV65519793; called by muse, mutect2
- MED12L | c.1143G>A p.W381* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV99854401, COSV99854898; called by muse, mutect2, varscan2
- MELK | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV99975008; called by muse, mutect2, varscan2
- MEP1A | c.256A>C p.N86H | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100043045; called by muse, mutect2, varscan2
- METTL17 | c.389T>G p.L130R | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100228341; called by muse, mutect2, varscan2
- MIA2 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99696902; called by muse, mutect2, varscan2
- MKI67 | c.8203G>T p.E2735* | Nonsense Mutation (SNP) | VAF 24/41 reads (59%) | catalogued as COSV100896917; called by muse, mutect2, varscan2
- MKLN1 | c.339A>C p.E113D | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100759982; called by muse, mutect2
- MMAA | c.193T>G p.L65V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV99850014; called by muse, mutect2, varscan2
- MMP12 | c.200T>C p.M67T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100405064; called by muse, mutect2, varscan2
- MMP21 | c.1108C>T p.R370* | Nonsense Mutation (SNP) | VAF 36/96 reads (38%) | catalogued as rs752375826, COSV100916656; called by muse, mutect2, varscan2
- MN1 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100179984, COSV100180103; called by muse, mutect2, varscan2
- MOGAT2 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as rs776690691, COSV52220556; called by muse, mutect2, varscan2
- MORC1 | c.223+2T>C p.X75_splice | Splice Site (SNP) | VAF 30/58 reads (52%) | catalogued as COSV99227522; called by muse, mutect2, varscan2
- MORC4 | c.1093A>G p.I365V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV99717533; called by muse, mutect2, varscan2
- MPDZ | c.5590G>A p.E1864K (on ENST00000319217 / NM_001330637.2; = p.E1835K on NM_003829.5) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776416799, COSV59920911; called by muse, mutect2, varscan2
- MPP2 | c.1031G>A p.R344Q (on ENST00000461854 / NM_001278372.2; = p.R320Q on NM_005374.5) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs751973227, COSV52237512; called by muse, mutect2, varscan2
- MPP7 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs35450618; called by muse, mutect2, varscan2
- MRGPRX4 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100049834; called by muse, mutect2, varscan2
- MROH9 | c.628A>C p.N210H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100882999; called by muse, mutect2, varscan2
- MROH9 | c.889A>G p.I297V | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as COSV63013167; called by muse, mutect2, varscan2
- MRPL18 | c.362A>G p.N121S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as COSV99277800; called by muse, mutect2, varscan2
- MRPL39 | c.944A>C p.K315T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV100221071; called by muse, mutect2
- MRS2 | c.311A>C p.K104T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99219101; called by muse, mutect2, varscan2
- MRTFB | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.09); catalogued as COSV100371740; called by muse, mutect2, varscan2
- MS4A5 | c.417C>A p.F139L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs1200811533, COSV100281098, COSV55740897; called by muse, mutect2, varscan2
- MSH2 | c.2749G>A p.A917T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs200581817, COSV99254466; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTMR10 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.212); catalogued as COSV100076326; called by muse, mutect2, varscan2
- MTMR11 | c.1568G>A p.S523N (on ENST00000439741 / NM_001145862.2; = p.S451N on NM_181873.3) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs374779123, COSV99641365; called by muse, mutect2, varscan2
- MTMR11 | c.1093A>C p.T365P (on ENST00000439741 / NM_001145862.2; = p.T293P on NM_181873.3) | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.946); catalogued as COSV99641367; called by muse, mutect2, varscan2
- MTSS1 | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100275469; called by muse, mutect2, varscan2
- MTUS1 | c.111A>C p.Q37H | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as COSV100029931; called by muse, mutect2, varscan2
- MUC4 | c.1151G>A p.S384N | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.22); catalogued as COSV100642085; called by muse, mutect2, varscan2
- MUC5B | c.11029A>G p.T3677A | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV101500684, COSV71589979; called by muse, mutect2
- MYBL1 | c.2044A>C p.N682H | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.823); catalogued as COSV101576596; called by muse, mutect2, varscan2
- MYCBP2 | c.5837T>C p.L1946S (on ENST00000357337; = p.L1984S on NM_015057.5) | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100631556; called by muse, mutect2, varscan2
- MYG1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs937356878, COSV99267098; called by muse, mutect2, varscan2
- MYH1 | c.2042A>C p.E681A | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99876710; called by muse, mutect2, varscan2
- MYH3 | c.164C>A p.S55Y | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV56866873, COSV99878738; called by muse, mutect2, varscan2
- MYLK | c.5289G>T p.M1763I | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as COSV100659525, COSV100659605; called by muse, mutect2, varscan2
- MYO3A | c.3449G>T p.R1150I | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56327080, COSV99779979; called by muse, mutect2, varscan2
- MYO5B | c.4459+2T>C p.X1487_splice | Splice Site (SNP) | VAF 23/54 reads (43%) | catalogued as COSV99546113; called by muse, mutect2, varscan2
- MYO6 | c.773A>C p.D258A | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV100889409; called by muse, mutect2, varscan2
- MYO7A | c.6395C>T p.A2132V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100265580; called by muse, mutect2, varscan2
- MYOM2 | c.3143G>A p.R1048Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs746759229, COSV50706990; called by muse, mutect2
- MYT1L | c.3437T>G p.F1146C | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101217369; called by muse, mutect2, varscan2
- N4BP2 | c.1481A>C p.E494A | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV99789172; called by muse, mutect2, varscan2
- NAA25 | c.2227C>T p.R743* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | catalogued as COSV55703882; called by muse, mutect2, varscan2
- NAPB | c.735+2T>C p.X245_splice | Splice Site (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100794106; called by muse, mutect2, varscan2
- NAV1 | c.5014T>G p.L1672V | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.92); catalogued as COSV99819545; called by muse, mutect2, varscan2
- NAXD | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV59396125; called by muse, mutect2, varscan2
- NBEAL1 | c.5789A>C p.D1930A | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101355604; called by muse, mutect2, varscan2
- NBPF1 | c.933G>T p.E311D | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs774511667, COSV101236670; called by muse, mutect2, varscan2
- NCKAP5 | c.3280G>T p.D1094Y | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV58462816, COSV58474131; called by muse, mutect2, varscan2
- NDC80 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 25/48 reads (52%) | catalogued as COSV55247492; called by muse, mutect2, varscan2
- NDEL1 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1434256360, COSV100233220; called by muse, mutect2, varscan2
- NDNF | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as rs745563516, COSV65633523; called by muse, varscan2
- NDST2 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs773724006, COSV100014321; called by muse, mutect2, varscan2
- NDUFS1 | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as rs762369653, COSV51909429; called by muse, mutect2, varscan2
- NECTIN3 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs200520350, COSV100162675; called by muse, mutect2, varscan2
- NEDD1 | c.1174A>C p.N392H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.275); catalogued as COSV99901260; called by muse, mutect2, varscan2
- NEDD1 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs762824150, COSV99901263; called by muse, mutect2, varscan2
- NEMF | c.2513C>T p.A838V | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs896324434, COSV53590711; called by muse, mutect2, varscan2
- NEMP1 | c.1234A>T p.S412C (on ENST00000300128 / NM_001130963.2; = p.S339C on NM_015257.3) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV100272277; called by mutect2, varscan2
- NETO2 | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.121); catalogued as COSV100292364; called by muse, mutect2, varscan2
- NEUROG1 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.162); catalogued as rs549630108, COSV100130841; called by muse, mutect2, varscan2
- NIBAN1 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100836569; called by muse, mutect2, varscan2
- NIM1K | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58141819; called by muse, mutect2, varscan2
- NIPSNAP3B | c.707T>G p.M236R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV101044532; called by muse, mutect2, varscan2
- NKAPL | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.17); catalogued as rs751561387, COSV59197122; called by muse, mutect2, varscan2
- NLRP5 | c.2639A>G p.H880R | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.109); catalogued as rs1457804598, COSV101173856; called by muse, mutect2, varscan2
- NMRAL1 | c.783C>A p.F261L | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs986441759, COSV52059560, COSV99361660, COSV99361895; called by muse, mutect2
- NOL8 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs746622958, COSV62634871; called by muse, mutect2, varscan2
- NOSTRIN | c.363G>T p.K121N (on ENST00000317647 / NM_001039724.4; = p.K43N on NM_052946.3) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV100473974; called by muse, mutect2, varscan2
- NPHP1 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 32/76 reads (42%) | catalogued as COSV100338446; called by muse, mutect2, varscan2
- NPIPB15 | c.546G>A p.Q182= | Splice Region (SNP) | VAF 26/182 reads (14%) | catalogued as COSV101466037; called by muse, mutect2, varscan2
- NRCAM | c.3334G>T p.E1112* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100695309, COSV61032682; called by muse, mutect2, varscan2
- NRK | c.2488C>T p.R830C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs866832781, COSV54605829; called by muse, mutect2, varscan2
- NRP1 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs1047454308, COSV55169878; called by muse, mutect2, varscan2
- NTRK2 | c.2237T>G p.I746S (on ENST00000323115 / NM_001369534.1; = p.I762S on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99458074; called by muse, mutect2, varscan2
- NUBP2 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.773); catalogued as rs199651045; called by muse, mutect2, varscan2
- NWD1 | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.738); catalogued as COSV100343545; called by muse, mutect2
- NXPE1 | c.566C>T p.A189V (on ENST00000424269; = p.A47V on NM_152315.5) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs760378519, COSV52627100; called by muse, mutect2, varscan2
- NYAP2 | c.26C>A p.S9Y | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV99796615, COSV99797080, COSV99798180; called by muse, mutect2, varscan2
- OR10AG1 | c.726C>A p.F242L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV56633688, COSV56635152; called by muse, mutect2, varscan2
- OR10R2 | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100936828, COSV63769543; called by muse, mutect2, varscan2
- OR10T2 | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.134); catalogued as COSV100555088; called by muse, mutect2, varscan2
- OR11H4 | c.884T>G p.F295C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs779234986, COSV100197596; called by muse, mutect2, varscan2
- OR1D5 | c.639C>A p.F213L | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV101643442, COSV73859568; called by muse, mutect2, varscan2
- OR2D3 | c.226T>C p.Y76H | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100505134; called by muse, mutect2, varscan2
- OR3A3 | c.770T>C p.V257A | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52166702, COSV99351524; called by muse, mutect2, varscan2
- OR4E2 | c.266G>T p.R89I | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100330145, COSV57732155; called by muse, mutect2
- OR51V1 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0.162); catalogued as COSV100343491, COSV58314473; called by muse, mutect2, varscan2
- OR52L1 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59989664; called by muse, mutect2, varscan2
- OR5AU1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369017740; called by muse, mutect2, varscan2
- OR5D14 | c.288C>A p.Y96* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as COSV100162562; called by muse, mutect2, varscan2
- OR5K3 | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs767922558, COSV101051676; called by muse, mutect2, varscan2
- OR5L2 | c.213C>A p.F71L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as COSV65723408; called by muse, mutect2, varscan2
- OR5M8 | c.406T>C p.S136P | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as COSV100510761; called by muse, mutect2, varscan2
- OR5T1 | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs529334335, COSV100479197; called by muse, mutect2, varscan2
- OR6C6 | c.91C>A p.L31I | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.021); catalogued as COSV100626516; called by muse, mutect2, varscan2
- OR7A5 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); catalogued as COSV59234280; called by muse, mutect2, varscan2
- OR8B2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs773729440, COSV100899488; called by muse, mutect2, varscan2
- OSMR | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV99953624; called by muse, varscan2
- PABPC3 | c.1662G>T p.K554N | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99879877; called by muse, mutect2, varscan2
- PABPC5 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs745619607, COSV100442646; called by muse, mutect2, varscan2
- PARP14 | c.3784A>C p.I1262L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101506338; called by muse, mutect2, varscan2
- PARP8 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV55858461; called by muse, mutect2, varscan2
- PAX6 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99570743; called by muse, mutect2, varscan2
- PCDHA13 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.171); catalogued as COSV99169377; called by muse, mutect2, varscan2
- PCDHA2 | c.1006A>C p.I336L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as COSV100974122; called by muse, mutect2, varscan2
- PCDHB6 | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as COSV99170833; called by muse, mutect2, varscan2
- PCDHGA12 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as rs754760314, COSV52759188; called by muse, mutect2
- PCDHGA3 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV53986325; called by muse, mutect2, varscan2
- PCDHGA4 | c.635A>G p.D212G | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.792); catalogued as COSV99545365; called by muse, mutect2, varscan2
- PCDHGA8 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as rs750579370, COSV54010878; called by muse, mutect2, varscan2
- PDE10A | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs774996040, COSV63091723; called by muse, mutect2, varscan2
- PDK3 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 34/61 reads (56%) | catalogued as COSV100998204; called by muse, mutect2, varscan2
- PEG3 | c.4589T>C p.M1530T | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV99690159; called by muse, mutect2, varscan2
- PEX5 | c.249G>T p.K83N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99871236; called by muse, mutect2, varscan2
- PHEX | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.739); catalogued as COSV101039611; called by muse, mutect2, varscan2
- PHF19 | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100384372; called by muse, mutect2, varscan2
- PHF3 | c.3088G>T p.E1030* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV50316005; called by muse, mutect2, varscan2
- PHF3 | c.4042C>T p.R1348C | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.385); catalogued as rs1182506621, COSV50317718; called by muse, mutect2, varscan2
- PHF8 | c.2366G>A p.R789Q (on ENST00000357988 / NM_001184896.1; = p.R753Q on NM_015107.3) | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1263803925, COSV57677476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHKA2 | c.2537C>T p.S846L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.153); catalogued as rs780316518, COSV66053504; called by muse, mutect2, varscan2
- PHKA2 | c.2305G>T p.D769Y | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV101177383; called by muse, mutect2, varscan2
- PIBF1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58328771; called by muse, mutect2, varscan2
- PIK3C2G | c.3544C>A p.L1182I (on ENST00000676171; = p.L1141I on NM_004570.5) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99853618; called by muse, mutect2, varscan2
- PIK3CG | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1226994105, COSV63247193; called by muse, mutect2, varscan2
- PIM1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs773910971, COSV100998747, COSV65164775; called by muse, mutect2, varscan2
- PJA1 | c.1333C>T p.R445* (on ENST00000361478 / NM_145119.4; = p.R257* on NM_022368.5) | Nonsense Mutation (SNP) | VAF 37/77 reads (48%) | catalogued as COSV64052550; called by muse, mutect2, varscan2
- PKD2L2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368989091; called by muse, mutect2, varscan2
- PKHD1L1 | c.1633T>G p.Y545D | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV101006718; called by muse, mutect2, varscan2
- PLA2G12A | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1485874019, COSV54669149, COSV54669573; called by muse, mutect2, varscan2
- PLA2G4D | c.1040A>C p.K347T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV99299984; called by muse, mutect2, varscan2
- PLCE1 | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.882); catalogued as rs771124727, COSV53337446; called by muse, mutect2, varscan2
- PLCE1 | c.5026A>C p.K1676Q | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53353243, COSV53371400; called by muse, mutect2, varscan2
- PLCZ1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs376713289; called by muse, mutect2, varscan2
- PLEK | c.136G>T p.G46* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV52252506, COSV99311199; called by muse, mutect2, varscan2
- PLEK | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV52253858; called by muse, mutect2, varscan2
- PLEKHA6 | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs138617775; called by muse, mutect2, varscan2
- PLEKHA7 | c.3245G>A p.R1082Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs150714472; called by muse, varscan2
- PLSCR4 | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV100724326; called by muse, mutect2, varscan2
- PLXNA4 | c.2533T>C p.W845R | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100326501; called by muse, mutect2, varscan2
- PNMA3 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.162); catalogued as COSV100937663; called by muse, mutect2, varscan2
- POLQ | c.3849G>T p.E1283D | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.782); catalogued as rs1380393118, COSV99952815; called by muse, mutect2, varscan2
- POLR3B | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs1043014755, COSV99943811; called by muse, mutect2, varscan2
- PON3 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | catalogued as COSV55699307; called by muse, mutect2
- POTEE | c.1621G>T p.E541* | Nonsense Mutation (SNP) | VAF 56/281 reads (20%) | catalogued as COSV100388785, COSV58229035; called by muse, mutect2, varscan2
- POTEF | c.2740G>T p.E914* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV100665270; called by muse, mutect2, varscan2
- POTEF | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.901); catalogued as rs1009657282, COSV100664710; called by muse, mutect2, varscan2
- PPEF2 | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as COSV54420543; called by muse, mutect2, varscan2
- PPFIA2 | c.3179G>A p.R1060H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100334928; called by muse, mutect2, varscan2
- PPIC | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs755709937, COSV60574765; called by muse, mutect2, varscan2
- PPIH | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as rs375438488, COSV100501152; called by muse, mutect2, varscan2
- PPIL4 | c.1084A>C p.K362Q | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as COSV99481878; called by muse, mutect2, varscan2
- PPL | c.3287A>G p.D1096G | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as COSV99278512; called by muse, mutect2, varscan2
- PPP1CA | c.440A>C p.K147T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.241); catalogued as COSV100335049, COSV56703255; called by muse, mutect2, varscan2
- PPP1R13B | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99161659; called by muse, mutect2, varscan2
- PPP1R3A | c.3245T>A p.F1082Y | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52887019; called by muse, mutect2, varscan2
- PPP2R5A | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1281369362, COSV54815387; called by muse, mutect2, varscan2
- PRG2 | c.310T>C p.C104R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV100315012; called by muse, mutect2, varscan2
- PRKCG | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs760409355, COSV99669452; called by muse, mutect2, varscan2
- PROSER1 | c.2815T>G p.S939A | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.16); catalogued as COSV100613002; called by muse, mutect2, varscan2
- PRPF4B | c.2661T>G p.I887M | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100528343; called by muse, mutect2, varscan2
- PRRC2A | c.2800C>T p.R934C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1436436810, COSV101051269; called by muse, mutect2, varscan2
- PRSS12 | c.809G>A p.S270N | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1377010316, COSV99628769; called by muse, mutect2, varscan2
- PRTG | c.1243T>C p.S415P | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as COSV101221476; called by muse, mutect2, varscan2
- PRTG | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.667); catalogued as rs371167586; called by muse, mutect2, varscan2
- PRUNE2 | c.5363C>T p.S1788F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as rs184412750; called by muse, mutect2, varscan2
- PSG11 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 100/214 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV100106102; called by muse, mutect2, varscan2
- PSMB9 | c.648C>A p.F216L | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV66399657; called by muse, mutect2, varscan2
- PTCD3 | c.980A>C p.K327T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as rs746789934, COSV99606587; called by muse, varscan2
- PTCHD4 | c.2398T>G p.F800V | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV100261483; called by muse, mutect2, varscan2
- PTEN | c.221G>T p.R74I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64288643, COSV64296223, COSV64303479; called by muse, mutect2, varscan2
- PTEN | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs746152219, CM1513163, COSV64296809, COSV64296832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTN | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | catalogued as COSV100781001, COSV61963233; called by muse, mutect2, varscan2
- PTPN12 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV50355226; called by muse, mutect2, varscan2
- PTPN20 | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99886359; called by muse, mutect2, varscan2
- PTPN21 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV100162449; called by muse, mutect2, varscan2
- PTPN3 | c.1318T>G p.L440V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99356156; called by muse, mutect2, varscan2
- PTPRC | c.497T>C p.L166S | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV100723050; called by muse, mutect2, varscan2
- PTPRU | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV100113592; called by muse, mutect2, varscan2
- PTS | c.391A>C p.K131Q | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV99738029; called by muse, mutect2, varscan2
- PWWP3A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/50 reads (32%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as COSV100262234; called by muse, varscan2
- R3HDML | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as rs1487303862, COSV99407267; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3529C>A p.H1177N (on ENST00000330843 / NM_001002814.3; = p.H543N on NM_025151.5) | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV99770420; called by muse, mutect2, varscan2
- RAB36 | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV99572318; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1545G>T p.Q515H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99921655; called by muse, mutect2, varscan2
- RABEP1 | c.2161G>T p.E721* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99336954; called by muse, mutect2, varscan2
- RABGEF1 | c.625C>T p.R209C (on ENST00000439720 / NM_001287061.2; = p.R196C on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.337); catalogued as COSV53165136; called by muse, mutect2, varscan2
- RABGGTB | c.431G>T p.R144I | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100175217; called by muse, mutect2, varscan2
- RAD54B | c.1840A>C p.N614H | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100280138; called by muse, mutect2, varscan2
- RAPGEF5 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.336); catalogued as rs768637186, COSV59778783; called by muse, mutect2, varscan2
- RARB | c.281A>G p.K94R (on ENST00000383772 / NM_001290216.2; = p.K87R on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV100412792; called by muse, mutect2
- RASSF2 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.138); catalogued as rs192780679; called by muse, mutect2, varscan2
- RB1 | c.1424A>G p.K475R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.797); catalogued as COSV99926439; called by muse, mutect2, varscan2
- RBBP5 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52704159; called by muse, mutect2, varscan2
- RBBP6 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as rs368671422; called by muse, mutect2, varscan2
- RBL1 | c.1678G>T p.E560* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100727271; called by muse, mutect2, varscan2
- RBM34 | c.1060G>T p.G354W | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100784038; called by muse, mutect2, varscan2
- RECQL | c.444A>C p.L148F | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100131355; called by muse, mutect2, varscan2
- RELCH | c.718A>C p.N240H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV99902680; called by muse, mutect2, varscan2
- REPS1 | c.2000C>A p.S667Y (on ENST00000450536 / NM_001286611.2; = p.S666Y on NM_031922.4) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.459); catalogued as COSV57808677; called by muse, mutect2, varscan2
- REV1 | c.1889A>G p.Y630C | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99301386; called by muse, mutect2, varscan2
- REV3L | c.4027A>C p.S1343R | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV100725617; called by muse, mutect2, varscan2
- RFC1 | c.2538+2T>C p.X846_splice (on ENST00000381897 / NM_001363496.2; = p.X845_splice on NM_002913.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 19/31 reads (61%) | catalogued as COSV100567976; called by muse, mutect2, varscan2
- RFPL4B | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as rs757633697, COSV101480722; called by muse, mutect2, varscan2
- RGS2 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV99343455; called by muse, mutect2, varscan2
- RILPL1 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as rs1273402938, COSV65302468; called by muse, mutect2, varscan2
- RIPOR3 | c.2797G>T p.E933* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99246639; called by muse, mutect2, varscan2
- RMI1 | c.597A>C p.E199D | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100366445; called by muse, mutect2, varscan2
- RNASEL | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as COSV100842636; called by muse, mutect2, varscan2
- RNF146 | c.38A>G p.N13S (on ENST00000368314 / NM_001242850.2; = p.N12S on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as COSV58931549; called by muse, mutect2, varscan2
- RNF220 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs575154952, COSV62404734; called by muse, mutect2, varscan2
- RNF25 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs200164624, COSV55306083; called by muse, mutect2, varscan2
- RNF41 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.518); catalogued as rs903589499, COSV100560330; called by muse, mutect2, varscan2
- RNF8 | c.18C>A p.F6L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs1217599816, COSV100009858; called by muse, mutect2, varscan2
- ROCK1 | c.1476G>T p.Q492H | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.414); catalogued as COSV101296598; called by muse, mutect2, varscan2
- RORC | c.1008G>T p.K336N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100562077, COSV59096075; called by muse, mutect2, varscan2
- ROS1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs140178288; called by muse, mutect2, varscan2
- RPL5 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs752867126, COSV59873410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RSBN1L | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs762959199, COSV58506405; called by muse, mutect2, varscan2
- RTL8B | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.116); catalogued as COSV101195648; called by muse, mutect2, varscan2
- RTN4 | c.3448A>G p.S1150G (on ENST00000337526 / NM_020532.5; = p.S157G on NM_007008.3) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100463821; called by muse, mutect2, varscan2
- RUBCN | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs777336467, COSV99584904; called by muse, mutect2, varscan2
- RUFY4 | c.741C>A p.F247L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100723195; called by muse, mutect2, varscan2
- RUNDC3B | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 20/49 reads (41%) | catalogued as COSV100407255; called by muse, mutect2, varscan2
- RUSC1 | c.800A>C p.K267T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99430211; called by muse, mutect2, varscan2
- RXYLT1 | c.303A>C p.Q101H | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99707075; called by muse, mutect2, varscan2
- RYR1 | c.2967A>C p.E989D | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV100616762; called by muse, mutect2, varscan2
- RYR2 | c.8145G>T p.E2715D | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.904); catalogued as rs200420897; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SACS | c.10536G>T p.E3512D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101207673; called by muse, mutect2, varscan2
- SACS | c.4474G>T p.E1492* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV66535403, COSV66545358; called by muse, mutect2, varscan2
- SAGE1 | c.2506C>T p.R836* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as rs782625354, COSV61012285; called by muse, mutect2, varscan2
- SAMD9 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as rs373775990, COSV66073210; called by muse, mutect2, varscan2
- SAMD9L | c.4568G>A p.R1523H | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs778834717, COSV59079879; called by muse, mutect2, varscan2
- SBF2 | c.3632C>A p.S1211Y | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1356162033, COSV99815523; called by muse, mutect2, varscan2
- SCG2 | c.1372A>G p.N458D | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV100544879; called by muse, mutect2, varscan2
- SCGN | c.466A>G p.T156A | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV100618837; called by muse, mutect2, varscan2
- SCLY | c.512T>C p.V171A (on ENST00000651534; = p.V163A on NM_016510.7) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.434); catalogued as COSV99616198; called by muse, mutect2, varscan2
- SCN1A | c.6026A>G p.K2009R (on ENST00000303395 / NM_001202435.3; = p.K1998R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100321760; called by muse, mutect2, varscan2
- SCN9A | c.5397C>A p.F1799L (on ENST00000303354; = p.F1788L on NM_002977.3) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV100313967; called by muse, mutect2, varscan2
- SCN9A | c.2045A>G p.D682G (on ENST00000303354; = p.D671G on NM_002977.3) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.355); catalogued as COSV100313972; called by muse, mutect2, varscan2
- SCYL3 | c.2008G>T p.D670Y (on ENST00000367770; = p.D616Y on NM_020423.7) | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99610110; called by muse, mutect2, varscan2
- SDK1 | c.5989T>G p.S1997A | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.045); catalogued as COSV101269752; called by muse, mutect2, varscan2
- SELP | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99740901; called by muse, mutect2
- SERPINB3 | c.60A>T p.R20S | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as COSV99380146; called by muse, mutect2, varscan2
- SETDB2 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV51643310; called by muse, mutect2, varscan2
- SETX | c.5617G>A p.E1873K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0.052); catalogued as rs775692275, COSV56378631, COSV56398415; called by muse, mutect2, varscan2
- SETX | c.5503G>A p.E1835K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.121); catalogued as rs143133190; ClinVar: uncertain significance; called by mutect2, varscan2
- SF3B1 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.439); catalogued as COSV100133988, COSV59209114; called by muse, mutect2, varscan2
- SGCE | c.861A>C p.E287D (on ENST00000647096; = p.E251D on NM_003919.3) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.962); catalogued as COSV99722863; called by muse, mutect2, varscan2
- SGO1 | c.1361A>C p.K454T (on ENST00000263753 / NM_001012410.5; = p.K185T on NM_138484.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV99768449; called by muse, mutect2, varscan2
- SH3GLB1 | c.233T>G p.F78C | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100990813; called by muse, mutect2, varscan2
- SHH | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM122189, COSV99793524; called by muse, mutect2, varscan2
- SHLD2 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs751251210, COSV100079473; called by muse, mutect2, varscan2
- SHPRH | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.991); catalogued as rs765387933, COSV99262612; called by muse, mutect2, varscan2
- SIGLEC1 | c.4904G>A p.R1635H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs377255910; called by muse, mutect2, varscan2
- SKIDA1 | c.1191T>G p.D397E | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as COSV101481335; called by muse, mutect2, varscan2
- SLC17A8 | c.1515G>T p.E505D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV100035781; called by muse, mutect2, varscan2
- SLC1A3 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 5/85 reads (6%) | catalogued as COSV99468109; called by muse, mutect2
- SLC1A6 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs746988953, COSV99694138; called by muse, mutect2, varscan2
- SLC25A24 | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as rs376157270; called by muse, mutect2, varscan2
- SLC25A28 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.377); catalogued as COSV100979633; called by muse, mutect2, varscan2
- SLC25A52 | c.835T>G p.F279V (on ENST00000672005; = p.F269V on NM_001034172.4) | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV99329786; called by muse, mutect2, varscan2
- SLC30A9 | c.1667G>T p.R556L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV100048037, COSV100048462; called by muse, mutect2, varscan2
- SLC35E4 | c.989T>C p.F330S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100299292; called by muse, mutect2, varscan2
465 further variants in this file (210 protein-altering or splice-affecting, 218 silent, 37 other) are not listed here.
